Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3T9, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3T9-01A (Primary Tumor).

[page 1 of 3]
Dual/Synchronous Primary, noted		☒

Pathology port

DOB
Physician:

Sex

Accession.

Collected.

Received:

Case type: Surgical Case

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) THYROID:

PAPILLARY THYROID CARCINOMA, LEFT LOBE (4.0 CM).

THE TUMOR INVADES LYMPHOVASCULAR SPACES AND IS EXTENSIVE TO EXTRATHYROIDAL SOFT TISSUE.

METASTATIC PAPILLARY THYROID CARCINOMA PRESENT IN TWO PERI-THYROIDAL LYMPH NODES (2/2). TUMOR EXTENDS TO PERIPHERAL MARGINS OF RESECTION.

(B) RULE OUT PARATHYROID:

Fibroadipose tissue. No parathyroid tissue seen.

(C) LEFT TRACHEA ESOPHAGEAL GROOVE:

SOLID POORLY DIFFERENTIATED CARCINOMA IN SOFT TISSUE.

(D) ANTERIOR TRACHEAL SURFACE:

METASTATIC CARCINOMA IN SOFT TISSUE.

(E) LEFT TRACHEA:

SOLID POORLY DIFFERENTIATED CARCINOMA OF THYROID IN SOFT TISSUE. (SEE COMMENT)

(F) LEFT TRACHEAL MARGIN

SOLID POORLY DIFFERENTIATED CARCINOMA OF THYROID IN SOFT TISSUE.

(G) TRACHEAL BIOPSY:

Respiratory mucosa, no tumor present.

Entire report and diagnosis completed by

COMMENT

Additional tissue sections and immunohistochemical studies will be performed to further categorize the solid component of this tumor. A supplemental report will follow.

ICD-O-3
carcinoma, papillary, thyroid
826013
Site: thyroid, NOS
C73.9 4-4-12

GROSS DESCRIPTION

(A) THYROID - A thyroidectomy specimen, 7.0 x 4.0 x 2.0 cm. The right lobe of the thyroid is grossly unremarkable and measures 4.0 x 1.5 x 1.0 cm. The tumor - distorted left thyroid lobe is virtually replaced by a tan firm, focally calcified mass, 4.0 x 3.2 x 2.0 cm. The tumor abuts the surface of the thyroid and the posterior aspect is irregular and roughened, with gross evidence of surgical cauterization. The cut surface of the mass is tan and solid; approximately 10% of the mass is calcified and resistant to cutting with a scalpel blade.

[page 2 of 3]
Surgical Pathology Report

DOB.

Sex

Physician:

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

The thyroid parenchyma of the right lobe is red-purple. Focally, two small tan nodules, 0.1 and 0.2 cm in greatest dimension are identified within the mid portion of the right lobe, grossly suggestive of secondary tumor foci.

A representative portion of the tumor and uninvolved thyroid parenchyma are submitted to the tumor bank.

SECTION CODE: A1, A2, frozen sections; A3-A5, representative sections of tumor; A6-A8, tumor and surrounding soft tissue and thyroid tissue; A9, deep surface of thyroid (heavily calcified); A10, additional section of tumor; A11, right lobe of thyroid with suspicious tan nodule; A12, grossly unremarkable parenchyma, right lobe of thyroid.

*FS/DX: ATYPICAL FOLLICULAR LESION, STRONGLY SUSPICIOUS FOR PAPILLARY THYROID CARCINOMA, DEFER TO PERMANENT.

(B) RULE OUT PARATHYROID - A 0.1 x 0.1 x 0.1 cm fragment of glistening, red tissue, weighing 0.0042 gm. In toto for frozen section, B.

*FS/DX: FRAGMENT OF FIBROADIPOSE TISSUE, NO PARATHYROID.

(C) LEFT TRACHEA ESOPHAGEAL GROOVE - A fragment of white rubbery tissue measures 1.6 x 0.8 x 0.6 cm. Specimen is submitted in toto in C, for frozen.

*FS/DX: FIBROUS TISSUE, INFILTRATED BY SOLID CARCINOMA.

(D) ANTERIOR TRACHEAL SURFACE - A fragment of pink-tan rubbery tissue measures 1.4 x 0.6 x 0.2 cm. The specimen is submitted in toto in D, for frozen.

*FS/DX: HYALINIZED FIBROUS TISSUE WITH DISTORTED ATYPICAL INFILTRATE HIGHLY SUSPICIOUS FOR CARCINOMA, DEFER TO PERMANENT.

(E) LEFT TRACHEA - A 1.5 x 1.0 x 0.5 cm fragment of red/tan cartilaginous and soft tissue, in toto for frozen section E.

*FS/DX: FIBROUS TISSUE AND CARTILAGE INFILTRATED BY SOLID CARCINOMA.

(F) LEFT TRACHEAL MARGIN - A fragment of pink-tan soft tissue measures 0.9 x 0.7 x 0.3 cm. The specimen is submitted in toto in F, frozen.

*FS/DX: FIBROUS TISSUE AND CARTILAGE INFILTRATED BY SOLID CARCINOMA.

(G) TRACHEAL BIOPSY - A tan-pink nonoriented irregular fragment of tissue (0.6 x 0.3 x 0.2 cm). In toto in G.

CLINICAL HISTORY

Thyroid nodule.

SNOMED CODES

T-B6000, M-80503

"Some tests reported here may have been developed and performance characteristics determined by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

[page 3 of 3]
Surgical Pathology Report

Department of Pathology,

DOB:

Sex:

Physician:

Accession:

Collected:

Received:

Pathologist:

Case type: Surgical Case

ADDENDUM

Addendum completed by

DIAGNOSIS

(E) LEFT TRACHEA:

The neoplastic cells are positive for TTF-1 and CK-19. This represents a poorly differentiated papillary thyroid carcinoma (non-anaplastic).

Released by:

Source: NCI Genomic Data Commons file 88305082-e238-45c4-b2b7-bfa8e0ba29d6 (TCGA-EL-A3T9.C6AF9429-7F8D-40ED-90D7-E91332C5C66B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).